Surgical pathology report (de-identified scan), TCGA case TCGA-ET-A3DV, project TCGA-THCA (Thyroid Carcinoma), tissue source site Johns Hopkins, specimen TCGA-ET-A3DV-01A (Primary Tumor).

IIA Discrepancy		☒

SPECIMEN TAKEN:

FINAL DIAGNOSIS -----

THYROID (TOTAL THYROIDECTOMY): PAPILLARY THYROID CARCINOMA, FOLLICULAR VARIANT (4.2 CM). THE CARCINOMA IS CIRCUMSCRIBED AND THINLY ENCAPSULATED WITH FOCAL EXTENSION OF THE CARCINOMA INTO THE TUMOR CAPSULE. NO DEFINITE VASCULAR INVASION IS IDENTIFIED. THE SURGICAL MARGINS OF EXCISION ARE NEGATIVE FOR TUMOR. THE CARCINOMA ARISES IN A BACKGROUND OF NODULAR HYPERPLASIA. ONE (1) LYMPH NODE AND ASSOCIATED FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR.

Part# 1: THYROID ~ The specimen is received fresh labeled and is designated as thyroid. The surgeon has marked the right superior lobe with a stitch. It consists of a grossly recognizable thyroid gland, weighing 37 grams. The right lobe appears enlarged, measuring 5.5 x 4 x 3 cm. The left lobe measures 3 x 2 x 0.7 cm. Bisection of the thyroid reveals a single dominant tan brown nodule, measuring 4.2 x 3.2 x 2.7 cm, located in the entire right lobe. The remaining thyroid parenchyma appears unremarkable. The entire capsule is submitted surrounding this nodule. Representative sections are submitted of isthmus and left lobe. ~ ~ SUMMARY OF SECTIONS ~ 5 - A-E - (ENTIRE RIGHT LOBE WITH CAPSULE) ~ 1 - F - (ISTHMUS) ~ 2 - G,H - (ENTIRE LEFT LOBE, BISECTED) ~ 8 - TOTAL - M ~

1CD-0-3

carcinoma, papillary, follicular variant
8340/3

Site: thyroid, NOS C73.9 lw
10/21/11

Source: NCI Genomic Data Commons file 03148182-9009-4eb6-8950-8723ef1e1575 (TCGA-ET-A3DV.D95F4F07-87EC-4668-ADC6-95BB3B097DB1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).